Surgical pathology report (de-identified scan), TCGA case TCGA-33-4582, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4582-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1. LUNG, LEFT LOWER LOBE (LOBECTOMY): INFILTRATING MODERATELY
DIFFERENTIATED SQUAMOUS CELL CARCINOMA (3.0 CM). TWO (2)
PERIBRONCHIAL LYMPH NODES ARE NEGATIVE FOR TUMOR. ALL MARGINS ARE
NEGATIVE FOR TUMOR. THE PATHOLOGIC STAGE IS T1N0MX.

2. LYMPH NODE, STATION 5 (EXCISION): TWO (2) LYMPH NODES NEGATIVE
FOR TUMOR.

3. LYMPH NODE, STATION 7 (EXCISION): TWO (2) LYMPH NODES NEGATIVE
FOR TUMOR.

4. LYMPH NODE, L11 (EXCISION): THREE (3) LYMPH NODES NEGATIVE FOR
TUMOR.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file d4188d1f-2045-44ca-876f-1fe173e742e3 (TCGA-33-4582.3C5A7297-2AAD-496B-A552-C570CBEE49B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).